Somatic mutation profile of tumor specimen ER-AD7D-TTM1-A (aliquot ER-AD7D-TTM1-A-1-0-D-A49S-35) from EXCEPTIONAL_RESPONDERS case ER-AD7D, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.6 years (19,226 days).
Specimen ER-AD7D-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f683c7d-dc08-415a-92d9-a65b6103b54c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AD7D-NT1-A (Solid Tissue Normal), aliquot ER-AD7D-NT1-A-1-0-D-A580-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68b2c537-a677-4634-8406-8c6303c60979

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 2, Missense Mutation 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 207/543 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4326del p.P1443Lfs*30 | Frame Shift Del (DEL) | VAF 87/458 reads (19%) | catalogued as COSV57332204; called by mutect2, pindel, varscan2
- APC | c.2379_2380del p.Y796Wfs*2 | Frame Shift Del (DEL) | VAF 143/347 reads (41%) | called by mutect2, pindel, varscan2
- CBFB | c.54dup p.R19* | Frame Shift Ins (INS) | VAF 115/355 reads (32%) | called by mutect2, pindel, varscan2
- GATA6 | c.1055dup p.P353Tfs*110 | Frame Shift Ins (INS) | VAF 108/195 reads (55%) | called by mutect2, pindel, varscan2
- HLA-C | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 211/415 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
